Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4743, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4743-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

with hepatic flexure mass biopsy adenoma.

Specimens Submitted:

1: SP: Right colectomy

DIAGNOSIS:

- 1) RIGHT COLON; RIGHT HEMICOLECTOMY:
- INVASIVE ADENOCARCINOMA, POORLY DIFFERENTIATED, WITH MUCINOUS AND MEDULLARY FEATURES.
- TUMOR LOCATION: ASCENDING COLON.
- TUMOR SIZE: LENGTH IS 7.1 CM, WIDTH IS 5.5 CM AND MAXIMAL THICKNESS IS 0.5 CM.
- GROSS CONFIGURATION: ULCERATING INFILTRATIVE.
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): NOT IDENTIFIED.
- TUMOR INVASION: INVASION INTO SUBSEROA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: SUSPECTED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS: FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL AND APPENDIX: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC 2002): PT3
- LYMPH NODES: NUMBER WITH METASTASES (0); NUMBER EXAMINED (27).
- THE PATHOLOGIC STAGE IS (AJCC 2002): pN0

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 3]
1). The specimen is received fresh, labeled "right colectomy" and consists of a segment of terminal ileum (10 cm long x 4 cm diameter), cecum and ascending colon (23 cm long x 5 to 9 cm diameter), appendix (4.5 cm long x 0.4 to 2 cm diameter) and attached adipose tissue / omentum (23 x 23 x 1.5 cm). The appendiceal and intestinal serosa is pink tan and smooth. The appendix contains a 2 cm fecalith and shows a normal mucosal surface. The ileal mucosa also appears normal. The specimen is opened to reveal a circumferential tumor (7.1 x 5.5 x 2.2 cm) constricting the cecal mucosa, and located 12 cm and 16 cm from the distal and proximal resection margins, respectively. The lesion is centrally necrotic with a heaped-up border, is firm and tan-yellow. It spares the ileocecal valve and appendiceal orifice by 4.5 and 5.2 cm, respectively. Sectioning shows the tumor to extend into the muscularis propria and possibly beyond it, into the pericolic adipose tissue. In this area, the serosa is puckered (inked black). The depth of invasion is approximately 0.5 cm in the ulcerated center. The remaining mucosa is normal. The specimen is submitted for lymph node dissection and all identified lymph nodes in the attached adipose tissue are submitted. Representative sections of the specimen are submitted for permanent sections and for [REDACTED]

Summary of sections:

P-- proximal margin shave
D -- distal margin shave
M-- mass, representative
MS -- mass to puckered serosal surface, representative
A -- appendix, representative
ICV -- ileocecal valve, representative
C-- colon, representative
I-- ileum, representative
LN-- lymph nodes

Summary of Sections:

Part 1: SP: Right colectomy

Block	Sect. Site	PCs
2	A	2
3	C	3
1	D	1
1	I	1
1	ICV	1
10	LN	20
3	M	3
3	MS	3
1	P	1

** Continued on next page **

[page 3 of 3]
** End of Report **

Source: NCI Genomic Data Commons file 61b26efd-4b49-4809-975c-9da6f60ce8f8 (TCGA-CM-4743.B3A7F5C8-89C3-4AB3-86D4-3577F1B58704.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).